Somatic mutation profile of tumor specimen C3L-00140-02 (aliquot CPT0001800005) from CPTAC case C3L-00140, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 70.8 years (25,869 days).
Specimen C3L-00140-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00ca97a3-43a1-45c8-b7d2-2c2ecab14bee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00140-31 (Blood Derived Normal), aliquot CPT0003960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de7db24f-0883-4bac-ac2c-ff807894594c

The open-access MAF lists 55 somatic variants for this specimen: 37 protein-altering or splice-affecting, 8 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 8, 5'Flank 3, Intron 2, 3'UTR 2, Nonsense Mutation 2, RNA 2, 5'UTR 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1901A>G p.D634G (on ENST00000288602 / NM_001374244.1; = p.D594G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs121913338, COSV56065695, COSV56224199, COSV56283955; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV66308606; called by muse, mutect2, varscan2
- EMILIN3 | c.1876G>A p.V626M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs770907842; called by muse, mutect2, varscan2
- MSN | c.1142G>T p.R381L | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as COSV64303958; called by muse, mutect2, varscan2
- RELN | c.6598G>A p.G2200R | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1224506694; called by muse, varscan2
- RPL5 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as rs1281806562; called by muse, mutect2, varscan2
- SEL1L | c.2200G>C p.D734H | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV60919024; called by muse, mutect2, varscan2
- SMR3B | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 17/111 reads (15%) | PolyPhen possibly damaging (0.83); catalogued as rs766013455; called by muse, mutect2, varscan2
- TBX1 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1014592830; called by muse, mutect2, varscan2
- TMCO1 | c.329A>T p.E110V (on ENST00000612311 / NM_001256164.1; = p.E59V on NM_019026.6) | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV63317640; called by muse, mutect2, varscan2
- TMEM19 | c.962T>A p.I321N | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV99876973; called by muse, mutect2, varscan2
- TTN | c.44521A>G p.I14841V (on ENST00000591111; = p.I7417V on NM_003319.4) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | PolyPhen probably damaging (0.978); catalogued as rs1029563364; called by muse, mutect2, varscan2
- ZNF705G | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 55/587 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs576676451; called by muse, mutect2, varscan2
- ANXA8 | c.239G>T p.S80I | Missense Mutation (SNP) | VAF 62/955 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATAD5 | c.1895A>G p.N632S | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP120 | c.1864G>T p.V622L | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, varscan2
- CPEB1 | c.1243G>T p.G415C (on ENST00000617958; = p.G355W on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERICH3 | c.3704C>A p.P1235Q | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ESPL1 | c.3944G>T p.R1315L | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- EYA4 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 62/324 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- FANCA | c.1136T>A p.L379Q | Missense Mutation (SNP) | VAF 74/481 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GBF1 | c.352C>G p.H118D | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR107 | c.1364-1G>T p.X455_splice | Splice Site (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- KDM2A | c.3242C>A p.S1081Y | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- KIF2B | c.1475C>A p.T492N | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KRT12 | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MACO1 | c.741G>T p.L247F | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MKNK2 | c.1175T>C p.L392P | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLRG1 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 33/203 reads (16%) | called by muse, mutect2, varscan2
- PLRG1 | c.501G>T p.M167I | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSMA6 | c.308A>T p.Y103F | Missense Mutation (SNP) | VAF 51/379 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RESF1 | c.2770C>T p.Q924* | Nonsense Mutation (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- SCAMP4 | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 30/243 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SIM2 | c.590A>C p.D197A | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SLC35D3 | c.583G>T p.V195F | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- STK11 | c.204_213delinsA p.D68_T71delinsE | In Frame Del (DEL) | VAF 20/212 reads (9%) | called by pindel, varscan2*
- TAMALIN | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 53/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNTNAP2 | c.324T>C p.D108= | Silent (SNP) | VAF 54/290 reads (19%) | catalogued as rs756947754; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- GRIN2B | c.2451C>T p.N817= | Silent (SNP) | VAF 37/274 reads (14%) | catalogued as rs1474375987; called by muse, mutect2, varscan2
- KLHL1 | c.153C>A p.P51= | Silent (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- NCF2 | c.840C>G p.V280= | Silent (SNP) | VAF 38/426 reads (9%) | catalogued as rs554005946; called by muse, mutect2
- OR7A17 | c.546T>C p.N182= | Silent (SNP) | VAF 29/199 reads (15%) | called by muse, mutect2, varscan2
- PDE6A | c.2406C>T p.I802= | Silent (SNP) | VAF 82/439 reads (19%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.4008A>G p.G1336= | Silent (SNP) | VAF 56/263 reads (21%) | called by muse, mutect2, varscan2
- TTLL2 | c.936C>A p.I312= | Silent (SNP) | VAF 41/235 reads (17%) | called by muse, mutect2, varscan2
- AC090825.1 | n.467T>A | RNA (SNP) | VAF 34/212 reads (16%) | called by muse, mutect2, varscan2
- DNAJC19 | c.*442C>T | 3'UTR (SNP) | VAF 116/501 reads (23%) | called by muse, mutect2, varscan2
- GUCD1 | chr22:24555717 G>A | 5'Flank (SNP) | VAF 69/455 reads (15%) | catalogued as rs1349808167; called by muse, mutect2, varscan2
- H2BP2 | n.1062-429C>A | Intron (SNP) | VAF 54/342 reads (16%) | called by muse, mutect2, varscan2
- MTFR1L | chr1:25820817 C>A | 5'Flank (SNP) | VAF 35/170 reads (21%) | called by muse, mutect2, varscan2
- PAX4 | c.*22G>A | 3'UTR (SNP) | VAF 45/348 reads (13%) | called by muse, mutect2, varscan2
- RELN | c.-41C>G | 5'UTR (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- TLCD2 | chr17:1712353 A>G | 5'Flank (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23342G>A | Intron (SNP) | VAF 75/429 reads (17%) | catalogued as rs184388078; called by muse, mutect2, varscan2
- VN1R10P | n.522C>T | RNA (SNP) | VAF 18/208 reads (9%) | catalogued as rs761618989; called by muse, mutect2
